Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4875, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4875-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (8.0 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(80% CLEAR CELLS,
20% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 3, INVASIVE
INTO THICK-WALLED
BLOOD VESSELS IN RENAL SINUS. (SEE COMMENT)

Margins of resection free of tumor.

(B) RIGHT ADRENAL GLAND:

METASTATIC RENAL CELL CARCINOMA IN ADRENAL GLAND.

COMMENT

The renal cell carcinoma in the right kidney does not invade into the perinephric adipose tissue or the renal vein. Tumor is present within large thick-walled blood vessels within the renal sinus, however, renal sinus adipose tissue is not involved by tumor.

GROSS DESCRIPTION

(A) RIGHT KIDNEY-A radical nephrectomy specimen (12.0 x 6.5 x 6.0 cm) with attached segment of ureter (1.0 cm in length and 0.6 cm in diameter).

Located in the center of the kidney is a well circumscribed mass (8.0 x 7.0 x 7.0 cm), surrounded by renal calyx/pelvis. The mass replaces four-fifths of the renal parenchyma. The tumor bulges into the renal sinus fat and perirenal fat. On cut surface the tumor is yellow with necrotic and hemorrhagic areas. The renal mass is 0.8 cm from the closest perirenal surface margin.

The uninvolved renal parenchyma is unremarkable. No lymph node is identified in the renal hilum.

NK CODE: The perirenal surface margin is inked blue.

SECTION CODE: A1, ureter, renal artery and renal vein margin; A2-A3, tumor in renal sinus; A4, tumor and perirenal fat margin; A5-A10, representative sections of tumor; A11, A12, tumor pushing into perinephric fat, contiguous section; A13, tumor and normal renal parenchyma; A14, normal renal parenchyma. A section of the tumor is submitted for possible electron microscopy studies.

(B) RIGHT ADRENAL GLAND - A fragment of yellow fatty tissue (10.0 x 5.0 x 2.0 cm), which contains an adrenal gland (5.5 x 2.5 x 1.0 cm). A well-circumscribed yellow, friable mass (3.0 x 1.5 x 0.9 cm) with areas of hemorrhage is located in the center of the adrenal gland. Representative sections of the mass and normal adrenal gland are submitted in B1-B4.

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

T-71000, M-83123, T-B3000, M-83126

Source: NCI Genomic Data Commons file c0acbacd-080e-4ad1-86d6-85eca9b4dd3c (TCGA-CJ-4875.9D234837-DD6A-4914-B1A6-D9699B57FDC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).